Somatic mutation profile of cancer-model specimen HCM-BROD-0962-C16-85A (3D Organoid, passage 10; aliquot HCM-BROD-0962-C16-85A-01D-A87L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0962-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G3; Age at diagnosis: 62.3 years (22,747 days).
Specimen HCM-BROD-0962-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a555156-afb6-4fcb-b446-fb8d69a4b5b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0962-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0962-C16-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f1394b2-f125-4e76-899d-71b38b27bfcc

The open-access MAF lists 153 somatic variants for this specimen: 108 protein-altering or splice-affecting, 32 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 32, Intron 8, Nonsense Mutation 6, 5'UTR 3, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, 5'Flank 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY6 | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 145/517 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57171037; called by muse, mutect2, varscan2
- ATP8A1 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as COSV52531473; called by muse, mutect2, varscan2
- C9orf72 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs545433336; called by muse, mutect2, varscan2
- CEP120 | c.1537G>T p.D513Y | Missense Mutation (SNP) | VAF 106/304 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV60269372; called by mutect2, varscan2
- CLPB | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 199/398 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs547532550, COSV104396671; called by muse, varscan2
- CMA1 | c.245C>A p.T82K | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759795995; called by mutect2, varscan2
- CNTNAP5 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 222/423 reads (52%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.709); catalogued as rs201163242, COSV70513494; called by muse, mutect2, varscan2
- COL17A1 | c.3286G>A p.V1096M | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62227268; called by muse, mutect2, varscan2
- CYP3A5 | c.98T>C p.F33S | Missense Mutation (SNP) | VAF 116/140 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867453902, COSV56118800; called by muse, mutect2, varscan2
- DCDC1 | c.2683T>A p.W895R (on ENST00000597505 / NM_001367979.1; = p.W2R on NM_020869.3) | Missense Mutation (SNP) | VAF 186/377 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100338696; called by muse, mutect2, varscan2
- DLC1 | c.3218G>A p.R1073Q (on ENST00000276297 / NM_001348081.2; = p.R636Q on NM_006094.5) | Missense Mutation (SNP) | VAF 51/474 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as rs750120068, COSV99366441; called by muse, mutect2, varscan2
- DST | c.12103C>G p.L4035V (on ENST00000361203 / NM_001374722.1; = p.L1623V on NM_015548.5) | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV55013772, COSV55021877; called by muse, mutect2
- FREM1 | c.5476G>A p.E1826K | Missense Mutation (SNP) | VAF 207/208 reads (100%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as COSV66521187; called by muse, mutect2, varscan2
- GRM6 | c.1628G>C p.C543S | Missense Mutation (SNP) | VAF 200/747 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs752010509; called by muse, mutect2, varscan2
- GTF2H1 | c.785T>A p.V262E | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV56377342; called by muse, mutect2
- HNRNPDL | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 209/517 reads (40%) | catalogued as rs921825556; called by muse, mutect2, varscan2
- ITPK1 | c.770C>G p.P257R | Missense Mutation (SNP) | VAF 33/761 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50896533, COSV99968439; called by muse, mutect2
- KIF5A | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 92/510 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as rs753975521; called by muse, mutect2, varscan2
- LSP1 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as rs771463495; called by muse, mutect2, varscan2
- MYO1F | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 132/329 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201191520; called by muse, mutect2, varscan2
- PDE4B | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as rs536471444; called by muse, mutect2, varscan2
- PLXND1 | c.3730G>A p.V1244M | Missense Mutation (SNP) | VAF 35/408 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs758594847; called by muse, mutect2
- PPP1R27 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 215/364 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs772428754; called by muse, mutect2, varscan2
- SACS | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 125/298 reads (42%) | catalogued as COSV66533286; called by muse, mutect2, varscan2
- SLC6A7 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57938312; called by muse, mutect2
- SPATA22 | c.231C>T p.T77= | Splice Region (SNP) | VAF 187/238 reads (79%) | catalogued as rs755124409, COSV52153427; called by muse, mutect2, varscan2
- TGM7 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 193/501 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.138); catalogued as rs754202746; called by muse, mutect2, varscan2
- VAMP4 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs771441555; called by mutect2, varscan2
- WDR17 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs1269575444, COSV54567796, COSV99708190; called by muse, mutect2, varscan2
- ZBTB17 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 60/535 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as rs755998745, COSV65272028; called by muse, mutect2, varscan2
- ZNF134 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 180/373 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV68696421; called by muse, mutect2, varscan2
- ZNF185 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 76/389 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100248580; called by muse, mutect2, varscan2
- ZSCAN18 | c.1096A>G p.K366E | Missense Mutation (SNP) | VAF 23/437 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs377691382; called by muse, mutect2
- ZXDB | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.346); catalogued as rs1470585368; called by muse, mutect2, varscan2
- ABCA6 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ADGRF4 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 84/333 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AFP | c.633del p.E212Nfs*2 | Frame Shift Del (DEL) | VAF 163/366 reads (45%) | called by mutect2, pindel, varscan2
- ANGPTL5 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 75/544 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD52 | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 80/756 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2
- ARG2 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP1B2 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- CDH4 | c.1532A>T p.H511L | Missense Mutation (SNP) | VAF 244/7134 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2
- CDRT15 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 166/341 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- CDRT15 | c.61A>C p.S21R | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- CENPT | c.725A>G p.Q242R | Missense Mutation (SNP) | VAF 148/254 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP20DC | c.2282_2283insTT p.Q761Hfs*15 (on ENST00000482387 / NM_001351530.2; = p.Q510Hfs*15 on NM_198463.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 42/385 reads (11%) | called by mutect2, pindel, varscan2
- CHST3 | c.958A>T p.T320S | Missense Mutation (SNP) | VAF 32/566 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- CLPTM1L | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 63/461 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL22A1 | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 48/742 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL22A1 | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 46/738 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUBN | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CWH43 | c.1078A>T p.I360F | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CYP2R1 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2
- CYSTM1 | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 13/422 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2
- DND1 | c.469G>C p.A157P | Missense Mutation (SNP) | VAF 24/741 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.511); called by muse, mutect2
- DYNC2H1 | c.5819G>C p.S1940T | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- FOXJ1 | c.389_435del p.I130Sfs*53 | Frame Shift Del (DEL) | VAF 64/676 reads (9%) | called by mutect2, pindel
- GLIPR2 | c.330G>C p.K110N | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- GLMP | c.989G>C p.C330S | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- GOLGA3 | c.2747C>G p.A916G | Missense Mutation (SNP) | VAF 60/570 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- GPR179 | c.5162G>A p.G1721E (on ENST00000621958; = p.G1720E on NM_001004334.4) | Missense Mutation (SNP) | VAF 166/821 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- GSDMC | c.1492A>C p.T498P | Missense Mutation (SNP) | VAF 31/530 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- HECTD3 | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- HLTF | c.834T>A p.F278L | Missense Mutation (SNP) | VAF 54/370 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ICMT | c.535T>G p.F179V | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ISM1 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 148/529 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA7 | c.289A>T p.S97C | Missense Mutation (SNP) | VAF 76/1083 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- KIAA1109 | c.2321C>G p.S774* | Nonsense Mutation (SNP) | VAF 108/476 reads (23%) | called by muse, mutect2, varscan2
- KMT2D | c.7420C>G p.P2474A | Missense Mutation (SNP) | VAF 88/873 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.369); called by muse, mutect2
- LRG1 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 18/419 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYST | c.9697T>C p.Y3233H | Missense Mutation (SNP) | VAF 61/459 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MICU3 | c.1469T>G p.L490* | Nonsense Mutation (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- MME | c.1417-7_1418del p.X473_splice | Splice Site (DEL) | VAF 28/239 reads (12%) | called by mutect2, pindel, varscan2
- MXRA5 | c.1616G>A p.W539* | Nonsense Mutation (SNP) | VAF 81/656 reads (12%) | called by muse, mutect2, varscan2
- MYEF2 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 72/574 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MYO9A | c.4976A>T p.D1659V | Missense Mutation (SNP) | VAF 59/492 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- NXPE4 | c.797A>C p.Y266S | Missense Mutation (SNP) | VAF 51/422 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5B17 | c.377A>T p.N126I | Missense Mutation (SNP) | VAF 21/625 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); called by muse, mutect2
- OR6T1 | c.50_51insA p.F17Lfs*4 | Frame Shift Ins (INS) | VAF 215/515 reads (42%) | called by mutect2, pindel, varscan2
- PIK3AP1 | c.1274T>G p.L425R | Missense Mutation (SNP) | VAF 257/503 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PLA1A | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.204); called by muse, mutect2
- PRKD2 | c.2045T>A p.L682Q | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRMT2 | c.463T>A p.C155S | Missense Mutation (SNP) | VAF 15/428 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2
- PRPF31 | c.1400C>G p.A467G | Missense Mutation (SNP) | VAF 151/368 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RBM6 | c.1988T>C p.I663T | Missense Mutation (SNP) | VAF 167/320 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- RGS22 | c.2331G>T p.M777I | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); called by muse, mutect2
- SCN7A | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 167/445 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SELPLG | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 71/533 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- SGSM1 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 56/662 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHLD3 | c.328del p.E110Nfs*47 | Frame Shift Del (DEL) | VAF 56/435 reads (13%) | called by mutect2, pindel, varscan2
- STK32A | c.459A>C p.L153F | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SULT2B1 | c.736T>A p.F246I (on ENST00000201586 / NM_177973.2; = p.F231I on NM_004605.2) | Missense Mutation (SNP) | VAF 43/540 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- SYNE1 | c.3580G>A p.V1194I (on ENST00000367255 / NM_182961.4; = p.V1201I on NM_033071.3) | Missense Mutation (SNP) | VAF 149/389 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYT1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 48/347 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TAOK1 | c.1505C>T p.T502I | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2
- TLK1 | c.456C>G p.Y152* | Nonsense Mutation (SNP) | VAF 90/206 reads (44%) | called by muse, mutect2, varscan2
- TLR4 | c.1845G>T p.K615N (on ENST00000355622 / NM_138554.5; = p.K575N on NM_003266.4) | Missense Mutation (SNP) | VAF 67/530 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMPRSS11B | c.775C>A p.H259N | Missense Mutation (SNP) | VAF 41/345 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM73 | c.704A>T p.E235V | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPAN10 | c.1043T>A p.L348Q (on ENST00000574882 / NM_001290212.1; = p.L310Q on NM_031945.4) | Missense Mutation (SNP) | VAF 28/764 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TTC39B | c.1087T>G p.Y363D | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- UGGT2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 129/282 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USH2A | c.5323A>G p.T1775A | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP12 | c.478A>C p.N160H | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.389); called by muse, mutect2
- WDFY4 | c.1727T>A p.I576N | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZC3H11B | c.1493A>G p.Q498R | Missense Mutation (SNP) | VAF 15/515 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2
- ZNF101 | c.959G>T p.R320I | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF536 | c.2074T>A p.S692T | Missense Mutation (SNP) | VAF 290/568 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AC138647.1 | c.339A>G p.G113= | Silent (SNP) | VAF 99/1067 reads (9%) | called by muse, mutect2
- APOB | c.6894A>G p.L2298= | Silent (SNP) | VAF 54/567 reads (10%) | called by muse, mutect2
- ATAD2 | c.135G>A p.A45= | Silent (SNP) | VAF 113/613 reads (18%) | catalogued as rs780389393; called by muse, mutect2, varscan2
- C20orf96 | c.858A>T p.L286= (on ENST00000360321 / NM_153269.3; = p.L285= on NM_080571.1) | Silent (SNP) | VAF 46/374 reads (12%) | called by muse, mutect2, varscan2
- CAPS2 | c.24T>G p.T8= | Silent (SNP) | VAF 45/386 reads (12%) | called by muse, mutect2, varscan2
- CBY3 | c.438G>A p.A146= | Silent (SNP) | VAF 102/772 reads (13%) | catalogued as rs1466123293; called by muse, mutect2, varscan2
- CEP126 | c.2763G>A p.V921= | Silent (SNP) | VAF 219/443 reads (49%) | called by muse, mutect2, varscan2
- CFAP20DC | c.2220T>G p.P740= (on ENST00000482387 / NM_001351530.2; = p.P489= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/447 reads (12%) | called by muse, mutect2, varscan2
- CYP21A2 | c.303G>T p.V101= | Silent (SNP) | VAF 168/379 reads (44%) | called by muse, mutect2, varscan2
- DDX1 | c.726C>T p.F242= | Silent (SNP) | VAF 61/535 reads (11%) | catalogued as rs201850199, COSV51837914; called by muse, mutect2, varscan2
- EML1 | c.1287C>T p.N429= | Silent (SNP) | VAF 53/344 reads (15%) | catalogued as rs200381411; called by muse, mutect2, varscan2
- GALNT18 | c.1290T>A p.I430= | Silent (SNP) | VAF 142/366 reads (39%) | called by muse, mutect2
- GEN1 | c.2577A>T p.T859= | Silent (SNP) | VAF 35/394 reads (9%) | called by muse, mutect2
- IFI44L | c.624T>A p.S208= | Silent (SNP) | VAF 67/432 reads (16%) | called by muse, mutect2, varscan2
- IGHV1-24 | c.249C>T p.F83= | Silent (SNP) | VAF 46/322 reads (14%) | catalogued as rs549832881; called by muse, mutect2, varscan2
- IZUMO3 | c.423T>C p.G141= (on ENST00000543880 / NM_001365008.2; = p.G135= on NM_001271706.1) | Silent (SNP) | VAF 207/208 reads (100%) | called by muse, mutect2, varscan2
- LAMA5 | c.7425C>T p.F2475= | Silent (SNP) | VAF 863/6274 reads (14%) | called by mutect2, varscan2
- LILRA4 | c.1332G>A p.V444= | Silent (SNP) | VAF 134/360 reads (37%) | catalogued as COSV99393265; called by muse, mutect2, varscan2
- NR5A2 | c.78G>T p.P26= | Silent (SNP) | VAF 111/342 reads (32%) | catalogued as COSV52656626; called by muse, mutect2, varscan2
- OR5B17 | c.378C>T p.N126= | Silent (SNP) | VAF 19/624 reads (3%) | called by muse, mutect2
- OTOG | c.5082C>T p.P1694= | Silent (SNP) | VAF 46/582 reads (8%) | catalogued as rs557377288; called by muse, mutect2
- PLK3 | c.1236G>C p.G412= | Silent (SNP) | VAF 33/282 reads (12%) | called by muse, mutect2, varscan2
- POSTN | c.535T>C p.L179= | Silent (SNP) | VAF 48/631 reads (8%) | called by muse, mutect2
- PTPRD | c.111T>A p.S37= | Silent (SNP) | VAF 22/262 reads (8%) | catalogued as rs753192942; called by muse, mutect2
- RGS12 | c.2754C>T p.H918= | Silent (SNP) | VAF 37/225 reads (16%) | catalogued as rs202155286; called by muse, mutect2, varscan2
- SCAF11 | c.15T>G p.T5= | Silent (SNP) | VAF 19/342 reads (6%) | called by muse, mutect2
- SETD2 | c.5478C>T p.R1826= | Silent (SNP) | VAF 40/526 reads (8%) | catalogued as rs557527064; ClinVar: likely benign; called by muse, mutect2
- SI | c.996A>G p.E332= | Silent (SNP) | VAF 30/268 reads (11%) | called by muse, mutect2, varscan2
- SNRNP48 | c.238T>C p.L80= | Silent (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- SOS2 | c.2973C>T p.N991= | Silent (SNP) | VAF 9/242 reads (4%) | called by muse, mutect2
- TMIGD2 | c.75G>A p.V25= | Silent (SNP) | VAF 60/430 reads (14%) | called by muse, mutect2, varscan2
- TNK2 | c.1074G>A p.Q358= | Silent (SNP) | VAF 88/587 reads (15%) | called by muse, mutect2, varscan2
- ABCG1 | c.287-11000G>A | Intron (SNP) | VAF 68/543 reads (13%) | called by muse, mutect2, varscan2
- AGAP3 | c.224-1216G>T | Intron (SNP) | VAF 68/280 reads (24%) | called by muse, mutect2, varscan2
- AGAP3 | c.224-1215C>T | Intron (SNP) | VAF 67/279 reads (24%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3169G>T | Intron (SNP) | VAF 26/251 reads (10%) | called by muse, mutect2, varscan2
- CNNM2 | c.-48_-15del | 5'UTR (DEL) | VAF 57/724 reads (8%) | called by mutect2, pindel
- DENND1B | c.83-20590C>A | Intron (SNP) | VAF 50/275 reads (18%) | called by muse, mutect2, varscan2
- MYC | c.-441T>G | 5'UTR (SNP) | VAF 339/691 reads (49%) | called by muse, mutect2, varscan2
- PPHLN1 | c.1024+32C>T | Intron (SNP) | VAF 213/571 reads (37%) | called by muse, mutect2, varscan2
- PPHLN1 | c.1126-65C>T | Intron (SNP) | VAF 154/445 reads (35%) | called by muse, mutect2, varscan2
- RARB | c.179-32791G>A | Intron (SNP) | VAF 66/561 reads (12%) | called by muse, mutect2, varscan2
- RSRC1 | chr3:158106011 ins T | 5'Flank (INS) | VAF 128/364 reads (35%) | catalogued as rs753723852; called by mutect2, pindel, varscan2
- SYNPO | chr5:150657053 G>A | 3'Flank (SNP) | VAF 64/345 reads (19%) | catalogued as rs144893816; called by muse, mutect2, varscan2
- TLK1 | c.-105C>T | 5'UTR (SNP) | VAF 28/634 reads (4%) | called by muse, mutect2
